Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2MH, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2MH-06A (Metastatic).

[page 1 of 2]
PathNet History Upload External
Client

DOB/Age/Sex:

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

Copies to: N/A

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

HISTORICAL REQUEST DETAILS

CLINICAL HISTORY

Malignant melanoma primary = 3.4mm deep (R) anterior chest wall.

SPECIMEN INFORMATION

1. Axillary contents.

MACROSCOPIC DESCRIPTION

"Right axillary contents". An irregular mass of fat and muscle, 180 x 170 x 80mm. Also included within the specimen bucket are four separate small jars and these will be described separately.

One jar is labelled specimen I and contains a grossly enlarged firm lymph node, 50 x 35 x 35mm. The cut surface of the node contains a pale and haemorrhagic tumour mass completely replacing normal node tissue. There is a small amount of fat attached and within the fat is a separate ?tumour nodule which may represent a second node or extranodal spread. The second focus of ?extranodal spread was identified 15 x 10 x 5mm.

- A. Main mass and second focus of ?extranodal spread.
- B. ?second node.

Second red top jar is labelled "specimen II" and contains a single firm pale lymph node and a small amount of attached fat, 30 x 20 x 15mm. The node cut surface is tan and focally haemorrhagic. No macroscopic extranodal spread seen.

- C. Longitudinal section.

The next red top jar is labelled "specimen III" and contains a single lymph node 10 x 10 x 5mm.

- D. One longitudinal section (within specimen III).

The final red top jar is labelled "specimen IV" and contains two fatty lymph nodes, 20 x 15 x 15mm, in total.

- E. 1 node bisected.
- F. 1 node bisected.

All embedded.

The main specimen was examined for lymph nodes. No orientating marks were

1CD-0-3
Melanoma, NOS 8720/3
Site: lymph node, axillary
C77.3
hw
8/24/11

[page 2 of 2]
Requested by: N/A

MRN/Name:

Location:

Accession:

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

identified and the specimen was examined beginning from the region of attached muscle.

- G. 3 nodes.
- H. 1 node bisected.
- J. 1 node.
- K. 2 nodes.
- L. 1 node in three pieces.
- M. 2 nodes.

MICROSCOPIC REPORT

"Right axillary contents". Metastatic malignant melanoma is present in eleven of the 16 lymph nodes identified. There is extranodal spread (A) and focal vascular invasion (B). Much of the neoplastic tissue is pleomorphic, poorly pigmented and intrasinusoidal.

Electronic signature

Verified by:

SUMMARY / KEY WORDS

Axillary lymph node - malignant melanoma, metastatic.
Haematopathology resection

Source: NCI Genomic Data Commons file 34cec316-6487-4b32-bbe9-d7b6ad2f4eff (TCGA-EE-A2MH.6C91C359-E679-46F3-9ADA-8958F1D1949E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).